Somatic mutation profile of tumor specimen 0DTNWI from CCDI case PBCJVC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 10.1 years (3,675 days).
Specimen 0DTNWI: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f2146bfe-2ea2-4c44-9777-dad42a516333.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DTNXA (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/85c126ad-4b58-4b94-bbc8-4a7dd5772dcb

The open-access MAF lists 13 somatic variants for this specimen: 3 protein-altering or splice-affecting, 4 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 4, Silent 4, 3'UTR 2, Missense Mutation 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SGK1 | c.131A>G p.N44S | Missense Mutation (SNP) | VAF 335/921 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs147939116; called by muse, mutect2, varscan2
- CDV3 | c.627-3T>A | Splice Region (SNP) | VAF 58/496 reads (12%) | called by muse, varscan2
- ZNF578 | c.1744T>G p.S582A | Missense Mutation (SNP) | VAF 29/837 reads (3%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.006); called by muse, mutect2
- GFI1B | c.702G>A p.T234= | Silent (SNP) | VAF 206/2144 reads (10%) | called by muse, mutect2
- GIMAP8 | c.1638G>A p.A546= | Silent (SNP) | VAF 68/2159 reads (3%) | catalogued as rs897850406, COSV56231089; called by muse, mutect2
- OR10Q1 | c.582C>T p.C194= | Silent (SNP) | VAF 183/1656 reads (11%) | catalogued as rs1215448149, COSV57470976; called by muse, mutect2, varscan2
- SEC16B | c.2436C>T p.S812= | Silent (SNP) | VAF 160/1769 reads (9%) | catalogued as rs766721116; called by muse, mutect2
- BBOF1 | c.*81A>T | 3'UTR (SNP) | VAF 64/1242 reads (5%) | called by muse, mutect2
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 48/384 reads (13%) | called by muse, varscan2
- CALCOCO2 | c.825+77T>A | Intron (SNP) | VAF 48/376 reads (13%) | called by muse, varscan2
- CRIPT | c.*53T>A | 3'UTR (SNP) | VAF 72/684 reads (11%) | called by muse, varscan2
- RBBP4 | c.485-97_485-96insCAAGATGTCTAAAGCTCTTAACATTTATAAATGA | Intron (INS) | VAF 0/200 reads (0%) | called by muse*, mutect2
- UBE3A | c.30-80T>C | Intron (SNP) | VAF 44/114 reads (39%) | called by muse, varscan2
